CCDI case PBBVEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/96429f55-a426-408e-ba91-b25dc03b338a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 13.3 years (4,850 days).

Biospecimens (3 samples)
- Sample 0DI6KG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6KU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI6L0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
